Somatic mutation profile of tumor specimen MBCProject_0102_T1_WES (aliquot MBCProject_0102_T1_WES_1) from CMI case MBCProject_0102, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 35.5 years (12,977 days).
Specimen MBCProject_0102_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Axilla; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bdebea7a-bd10-4a8e-acfb-e6a5e2cfb984.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0102_SALIVA (Saliva), aliquot MBCProject_0102_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab49137e-193b-4175-aadd-7d958d1722b9

The open-access MAF lists 56 somatic variants for this specimen: 33 protein-altering or splice-affecting, 16 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 16, 3'UTR 4, Nonsense Mutation 2, 5'UTR 1, RNA 1, Splice Region 1, In Frame Ins 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS18 | c.497C>G p.S166* | Nonsense Mutation (SNP) | VAF 19/245 reads (8%) | catalogued as COSV99271966; called by muse, mutect2
- CNGB3 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV60686494; called by muse, mutect2
- FOXL1 | c.707C>T p.T236I | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs1031414327; called by muse, mutect2, varscan2
- IGLV2-14 | c.47-1G>A p.X16_splice | Splice Site (SNP) | VAF 22/275 reads (8%) | catalogued as rs575584498; called by muse, mutect2
- IL20RA | c.957T>G p.D319E | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.514); catalogued as rs1334018553; called by muse, mutect2
- LIPH | c.207G>C p.K69N | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.461); catalogued as COSV99956027; called by muse, mutect2, varscan2
- LRP1B | c.2746G>C p.D916H | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63341890; called by muse, mutect2
- PITPNM2 | c.2759G>A p.R920Q | Missense Mutation (SNP) | VAF 15/163 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1450492351; called by muse, mutect2
- A2M | c.3561G>T p.Q1187H | Missense Mutation (SNP) | VAF 38/412 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); called by muse, mutect2
- ABCA1 | c.2402G>A p.G801D | Missense Mutation (SNP) | VAF 36/456 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCC3 | c.168_173dup p.R57_H58insQR | In Frame Ins (INS) | VAF 73/756 reads (10%) | called by mutect2, pindel
- ANXA13 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 8/179 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSNK1G2 | c.1019C>A p.T340N | Missense Mutation (SNP) | VAF 46/492 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2
- DNAH5 | c.12500G>T p.G4167V | Missense Mutation (SNP) | VAF 21/619 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); called by muse, mutect2
- FBN1 | c.6495A>T p.V2165= | Splice Region (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2, varscan2
- GALNT9 | c.442C>G p.Q148E | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- H6PD | c.836T>G p.L279R | Missense Mutation (SNP) | VAF 124/1184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- HECTD3 | c.227G>C p.G76A | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- KIF21B | c.3118G>T p.A1040S | Missense Mutation (SNP) | VAF 25/376 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- KMT2B | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 22/239 reads (9%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.219); called by muse, mutect2
- MMRN1 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 43/478 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.058); called by muse, mutect2
- MTMR8 | c.2076G>T p.K692N | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.264); called by muse, mutect2
- MTUS2 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 40/422 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2
- MYOCD | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NCAN | c.1014C>G p.F338L | Missense Mutation (SNP) | VAF 28/325 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.926); called by muse, mutect2
- PDE10A | c.1792C>T p.Q598* | Nonsense Mutation (SNP) | VAF 42/454 reads (9%) | called by muse, mutect2
- SESN2 | c.727A>G p.R243G | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- SHANK1 | c.2777C>T p.T926M | Missense Mutation (SNP) | VAF 23/301 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- SLAMF1 | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 48/528 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); called by muse, mutect2
- STX5 | c.718T>G p.S240A | Missense Mutation (SNP) | VAF 52/542 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- TOMM40 | c.1039C>T p.H347Y | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2
- TRIO | c.3583A>G p.R1195G | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF853 | c.1519C>T p.H507Y | Missense Mutation (SNP) | VAF 33/286 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ANOS1 | c.36C>G p.L12= | Silent (SNP) | VAF 30/411 reads (7%) | called by muse, mutect2
- AXL | c.1674C>T p.D558= (on ENST00000301178 / NM_021913.5; = p.D549= on NM_001699.6) | Silent (SNP) | VAF 24/214 reads (11%) | catalogued as rs771425371; called by muse, mutect2, varscan2
- BCL11B | c.1401C>A p.A467= (on ENST00000357195 / NM_001282237.2; = p.A396= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 64/778 reads (8%) | called by muse, mutect2
- CHST10 | c.792G>C p.V264= | Silent (SNP) | VAF 26/256 reads (10%) | called by muse, mutect2, varscan2
- CTIF | c.333C>A p.A111= | Silent (SNP) | VAF 45/349 reads (13%) | called by muse, mutect2, varscan2
- CUX2 | c.2466C>T p.R822= | Silent (SNP) | VAF 46/458 reads (10%) | called by muse, mutect2
- HECTD3 | c.2004A>G p.L668= | Silent (SNP) | VAF 58/726 reads (8%) | called by muse, mutect2
- KNDC1 | c.2931C>A p.L977= | Silent (SNP) | VAF 22/198 reads (11%) | called by muse, mutect2, varscan2
- NIN | c.1140C>G p.V380= | Silent (SNP) | VAF 19/171 reads (11%) | called by muse, mutect2, varscan2
- PEAR1 | c.84C>T p.T28= | Silent (SNP) | VAF 57/406 reads (14%) | called by muse, mutect2, varscan2
- PPL | c.3516G>A p.E1172= | Silent (SNP) | VAF 52/764 reads (7%) | catalogued as rs941090241; called by muse, mutect2
- SCN8A | c.1881G>A p.S627= | Silent (SNP) | VAF 25/194 reads (13%) | called by muse, mutect2, varscan2
- SELP | c.1692A>C p.P564= | Silent (SNP) | VAF 12/77 reads (16%) | called by muse, mutect2, varscan2
- SIGLEC12 | c.1767C>T p.S589= (on ENST00000291707 / NM_053003.4; = p.S471= on NM_033329.2) | Silent (SNP) | VAF 28/434 reads (6%) | catalogued as rs755647696, COSV52463733; called by muse, mutect2
- SSC5D | c.4182C>G p.S1394= | Silent (SNP) | VAF 42/668 reads (6%) | called by muse, mutect2
- ZAN | c.912C>T p.H304= | Silent (SNP) | VAF 26/213 reads (12%) | catalogued as rs376185033; called by muse, mutect2, varscan2
- ARMC4 | c.*37T>C | 3'UTR (SNP) | VAF 9/85 reads (11%) | catalogued as rs956980900; called by muse, mutect2
- EFEMP2 | c.*283G>A | 3'UTR (SNP) | VAF 43/379 reads (11%) | catalogued as rs373353116; called by muse, mutect2, varscan2
- GVINP1 | n.5774T>G | RNA (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- SCN4B | c.*2888C>T | 3'UTR (SNP) | VAF 23/196 reads (12%) | called by muse, mutect2, varscan2
- SMTN | c.-80-254G>A | Intron (SNP) | VAF 14/188 reads (7%) | catalogued as rs1182284709; called by muse, mutect2
- TMCO1 | c.*3461G>T | 3'UTR (SNP) | VAF 9/86 reads (10%) | catalogued as rs1255188835; called by muse, mutect2, varscan2
- TPRN | c.-6C>T | 5'UTR (SNP) | VAF 17/160 reads (11%) | called by muse, mutect2, varscan2
